Somatic mutation profile of tumor specimen TARGET-10-PAPESY-09A (aliquot TARGET-10-PAPESY-09A-01D) from TARGET case TARGET-10-PAPESY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (818 days).
Specimen TARGET-10-PAPESY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7dbbced5-c110-4be6-8a2f-8b6c658fdc5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPESY-14A (Bone Marrow Normal), aliquot TARGET-10-PAPESY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c0ccd77-238e-498a-bfce-72b59a21c617

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 17/88 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OR5M3 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56566607; called by muse, mutect2, varscan2
- TMEM94 | c.1176dup p.T393Dfs*55 | Frame Shift Ins (INS) | VAF 30/142 reads (21%) | catalogued as rs746649748; called by mutect2, pindel, varscan2
- TRIM32 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs888686561, COSV100528956; called by muse, mutect2, varscan2
- VPS4A | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- FLNA | c.1053G>A p.T351= | Silent (SNP) | VAF 86/173 reads (50%) | called by muse, mutect2, varscan2
- MRPL22 | c.393G>A p.R131= | Silent (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- GPAT3 | c.1126-104G>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- MIR9-1HG | n.574+173G>T | Intron (SNP) | VAF 15/34 reads (44%) | catalogued as COSV100024037; called by muse, mutect2, varscan2
